Gene-level copy-number profile of tumor specimen TCGA-QR-A708-01A from TCGA case TCGA-QR-A708, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 44.3 years (16,170 days).
Specimen TCGA-QR-A708-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.a576c1ae-b8c6-4279-ab67-08998890dceb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QR-A708-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate.
https://portal.gdc.cancer.gov/files/a2adfb00-2595-4a2b-bdaa-efdb92cb182c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 10,048; copy number 2: 49,127; copy number 3: 550; copy number 4: 62; copy number 5: 8.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:56,718,789–56,996,757, 5 genes (within-gene range 0–1): FYB2, AL360295.1, C8A, C8B, AL161740.1.
- chr1:169,511,951–169,586,588, 1 gene: F5.
- chr1:177,392,667–178,038,007, 6 genes (within-gene range 0–1): AL136114.1, LINC01741, SEC16B, CRYZL2P-SEC16B, CRYZL2P, AL359075.1.
- chr5:155,491,336–155,493,598, 1 gene: AC008725.1.
- chr6:85,257,328–85,257,694, 1 gene: AL122016.1.
- chr8:105,737,280–105,737,765, 1 gene: RPL12P24.
- chr11:5,430,653–5,441,514, 2 genes: OR51K1P, OR51I1.
- chr11:21,383,801–21,383,909, 1 gene: RNA5SP337.
- chr11:81,552,226–81,556,425, 2 genes: MTND4LP18, MTND6P25.
- chr11:112,977,353–112,977,420, 1 gene: RNU7-187P.
- chr16:52,198,012–52,227,956, 1 gene (within-gene range 0–1): AC007333.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:6,819,463–7,141,544, 8 genes, copy number 5 (within-gene range 3–5): NRIR, CMPK2, RSAD2, AC017076.1, GRASLND, RNF144A, AC068481.1, RN7SKP112.

Autosomal genes at a single copy (total copy number 1): 10,037. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
